Somatic mutation profile of tumor specimen TCGA-92-7341-01A (aliquot TCGA-92-7341-01A-31D-2042-08) from TCGA case TCGA-92-7341, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 71.6 years (26,134 days).
Specimen TCGA-92-7341-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d4ae61f4-974f-4e8e-8dfc-16fee26cbb04.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-92-7341-10A (Blood Derived Normal), aliquot TCGA-92-7341-10A-01D-2042-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2c85ad96-2a71-4d71-b416-a66f819e389d

The open-access MAF lists 189 somatic variants for this specimen: 139 protein-altering or splice-affecting, 47 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 126, Silent 47, Nonsense Mutation 7, Frame Shift Del 3, RNA 2, Splice Site 1, In Frame Del 1, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.85G>C p.D29H | Missense Mutation (SNP) | VAF 8/38 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519920, COSV67960002, COSV67960389, COSV67960852; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.661G>T p.E221* | Nonsense Mutation (SNP) | VAF 10/27 reads (37%) | catalogued as rs786201592, COSV52735606, COSV52751148, COSV52783951; ClinVar: pathogenic; called by muse, mutect2
- ACE2 | c.1429T>C p.W477R | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99382964; called by muse, mutect2, varscan2
- ADGRE2 | c.2187G>T p.M729I | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.326); catalogued as COSV100216238; called by muse, mutect2, varscan2
- AHNAK | c.11311G>T p.E3771* | Nonsense Mutation (SNP) | VAF 80/210 reads (38%) | catalogued as COSV99948358; called by muse, mutect2, varscan2
- ALDH1B1 | c.712A>G p.I238V | Missense Mutation (SNP) | VAF 43/84 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs551776658, COSV100890959; called by muse, mutect2, varscan2
- ALDH8A1 | c.94A>G p.T32A | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as rs1424520257, COSV99664851; called by muse, mutect2, varscan2
- ALPG | c.1369G>A p.A457T | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.494); catalogued as COSV54965181, COSV99779394; called by muse, mutect2, varscan2
- ANKRD27 | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100042965; called by muse, mutect2
- ANKRD34B | c.1159G>A p.G387S | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.95); PolyPhen benign (0.005); catalogued as rs373195260; called by muse, mutect2, varscan2
- APLP1 | c.553G>T p.G185C | Missense Mutation (SNP) | VAF 36/166 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV55707281, COSV99697765; called by muse, mutect2, varscan2
- ARHGEF4 | c.73G>T p.A25S | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.027); catalogued as rs773167697, COSV100388394; called by muse, mutect2, varscan2
- ATP13A3 | c.1220A>G p.Y407C | Missense Mutation (SNP) | VAF 113/194 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1429325653, COSV99757360; called by muse, mutect2, varscan2
- B4GALT6 | c.774T>G p.Y258* | Nonsense Mutation (SNP) | VAF 12/36 reads (33%) | catalogued as COSV99380158; called by muse, mutect2, varscan2
- BAZ2A | c.3649C>G p.P1217A | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs1276589843, COSV99466846; called by muse, mutect2
- BPIFB1 | c.854G>T p.S285I | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.123); catalogued as rs140267782, COSV99487490; called by muse, mutect2
- C1orf116 | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.048); catalogued as rs529972966, COSV100847963, COSV63944465; called by muse, mutect2, varscan2
- CACNA1H | c.613C>T p.R205W | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764822234, COSV61990780; called by muse, mutect2, varscan2
- CAND2 | c.3008A>T p.H1003L (on ENST00000456430 / NM_001162499.2; = p.H910L on NM_012298.3) | Missense Mutation (SNP) | VAF 43/73 reads (59%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV99929415; called by muse, mutect2, varscan2
- CARD6 | c.1981T>C p.F661L | Missense Mutation (SNP) | VAF 17/277 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV99620985; called by muse, mutect2
- CARD6 | c.2394A>T p.R798S | Missense Mutation (SNP) | VAF 28/489 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.037); catalogued as COSV99620987; called by muse, mutect2
- CCT4 | c.433A>G p.I145V | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs762811515, COSV101075281; called by muse, mutect2, varscan2
- CHRM5 | c.1163A>C p.D388A | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT tolerated (0.8); PolyPhen benign (0.089); catalogued as COSV101271991; called by muse, mutect2, varscan2
- COL27A1 | c.2716C>T p.P906S | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100621126; called by muse, mutect2
- COPE | c.10C>G p.P4A | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.005); catalogued as COSV99447670; called by muse, mutect2, varscan2
- CPXCR1 | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.929); catalogued as COSV99342284; called by muse, mutect2, varscan2
- CREB3L4 | c.730G>C p.G244R | Missense Mutation (SNP) | VAF 45/81 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99665783; called by muse, mutect2, varscan2
- CWH43 | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs747730162, COSV56938295; called by muse, mutect2, varscan2
- CYP4F8 | c.1250G>A p.G417E | Missense Mutation (SNP) | VAF 122/342 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs780551193, COSV57853254; called by muse, mutect2, varscan2
- CYSLTR2 | c.904C>A p.P302T | Missense Mutation (SNP) | VAF 47/87 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99935301; called by muse, mutect2, varscan2
- DNAH7 | c.5621G>A p.R1874Q | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as rs1274108178, COSV56774235; called by muse, mutect2, varscan2
- DNHD1 | c.13805T>C p.L4602P | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs1452878053, COSV99600491; called by muse, mutect2, varscan2
- DUSP5 | c.703A>G p.T235A | Missense Mutation (SNP) | VAF 29/146 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100851917; called by muse, mutect2, varscan2
- DYNC2H1 | c.6532C>G p.H2178D | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV100519032, COSV62096612; called by muse, mutect2, varscan2
- EIF4G1 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 47/369 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as COSV100072035; called by muse, mutect2, varscan2
- ERGIC1 | c.737G>A p.R246Q | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as rs566933192, COSV101194929, COSV101194976; called by muse, mutect2, varscan2
- ESF1 | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs751200578, COSV99176406; called by muse, mutect2, varscan2
- EVX2 | c.149G>A p.S50N | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as COSV100420745; called by muse, mutect2, varscan2
- FAM135A | c.1967C>A p.T656K (on ENST00000370479 / NM_001351599.1; = p.T443K on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.996); catalogued as COSV99526137; called by muse, mutect2
- FAM47C | c.769A>G p.S257G | Missense Mutation (SNP) | VAF 38/54 reads (70%) | SIFT tolerated (0.28); PolyPhen benign (0.188); catalogued as COSV100792783; called by muse, mutect2, varscan2
- FAM47C | c.2107C>A p.H703N | Missense Mutation (SNP) | VAF 35/60 reads (58%) | SIFT tolerated (0.37); PolyPhen benign (0.3); catalogued as COSV100792786; called by muse, mutect2, varscan2
- FAT1 | c.9928G>T p.G3310* | Nonsense Mutation (SNP) | VAF 35/48 reads (73%) | catalogued as COSV101499417; called by muse, mutect2, varscan2
- FGD5 | c.1418C>T p.A473V | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs763962573, COSV99548590, COSV99548743; called by muse, mutect2, varscan2
- FLG | c.5834C>A p.S1945Y | Missense Mutation (SNP) | VAF 22/365 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as rs1050534016, COSV100911784, COSV64247044; called by muse, mutect2
- FLG | c.5833T>C p.S1945P | Missense Mutation (SNP) | VAF 24/368 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as rs1277310700, COSV100911785; called by muse, mutect2
- FOLH1 | c.1336G>A p.G446S | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.075); catalogued as rs1192771721, COSV99923494; called by muse, mutect2, varscan2
- FOLR3 | c.191C>G p.A64G | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.238); catalogued as COSV100281814; called by muse, mutect2
- GABRA1 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.026); catalogued as COSV99196081; called by muse, mutect2, varscan2
- GLIS3 | c.311G>T p.G104V | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.714); catalogued as COSV101127751; called by muse, mutect2, varscan2
- GLIS3 | c.310G>T p.G104* | Nonsense Mutation (SNP) | VAF 26/66 reads (39%) | catalogued as COSV101127752, COSV67949645; called by muse, mutect2, varscan2
- GNB4 | c.796C>T p.H266Y | Missense Mutation (SNP) | VAF 13/198 reads (7%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.903); catalogued as COSV99224373; called by muse, mutect2
- GPR158 | c.827G>T p.S276I | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.065); catalogued as COSV100893935; called by muse, varscan2
- GUCY2F | c.1646C>T p.S549F | Missense Mutation (SNP) | VAF 68/120 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV99485302; called by muse, mutect2, varscan2
- HHAT | c.1111A>T p.T371S | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.438); catalogued as COSV99805178; called by muse, mutect2, varscan2
- HOXA3 | c.874C>A p.Q292K | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.444); catalogued as COSV100415561; called by muse, mutect2, varscan2
- HOXA9 | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.068); catalogued as rs759116325, COSV100604495, COSV58655820; called by muse, mutect2, varscan2
- HYDIN | c.1724G>C p.G575A | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99863833; called by muse, mutect2
- IKBKE | c.478G>T p.A160S | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100898321, COSV100898398; called by muse, mutect2, varscan2
- IMPDH1 | c.238A>G p.I80V (on ENST00000470772 / NM_001142573.2; = p.I165V on NM_000883.4) | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.102); catalogued as COSV100118732; called by muse, mutect2, varscan2
- KIAA1109 | c.7414T>C p.S2472P | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); catalogued as COSV99167213; called by muse, mutect2, varscan2
- KRT76 | c.94T>C p.C32R | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0.035); catalogued as COSV100196342; called by muse, mutect2, varscan2
- LATS1 | c.3164A>C p.E1055A | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT tolerated (0.67); PolyPhen benign (0.012); catalogued as COSV53598799; called by muse, mutect2, varscan2
- MAP4 | c.3067G>T p.V1023F | Missense Mutation (SNP) | VAF 32/53 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99275767; called by muse, mutect2, varscan2
- MBL2 | c.200G>A p.R67K | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.6); catalogued as COSV100906368; called by muse, mutect2, varscan2
- MED25 | c.1271C>T p.T424M | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.375); catalogued as COSV57207551; called by muse, mutect2, varscan2
- MGAT1 | c.1046T>G p.L349R | Missense Mutation (SNP) | VAF 16/59 reads (27%) | PolyPhen probably damaging (0.995); catalogued as COSV100286755; called by muse, mutect2, varscan2
- MIOS | c.268A>T p.T90S | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.019); catalogued as COSV100402865; called by muse, mutect2, varscan2
- MYL7 | c.17C>A p.A6E | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV99790048; called by muse, mutect2, varscan2
- NAT8 | c.143G>T p.G48V | Missense Mutation (SNP) | VAF 34/162 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.52); catalogued as COSV99722050; called by muse, mutect2, varscan2
- NDUFAF5 | c.391A>G p.T131A | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.57); PolyPhen benign (0.026); catalogued as COSV100962168; called by muse, mutect2
- NEUROD6 | c.445A>G p.I149V | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.042); catalogued as COSV99774110; called by muse, mutect2, varscan2
- NFAT5 | c.2120A>G p.Q707R | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV100590964; called by muse, mutect2, varscan2
- NHS | c.4822A>G p.I1608V | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101196749; called by muse, mutect2, varscan2
- OR11L1 | c.376A>T p.I126F | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.295); catalogued as COSV100869449, COSV63313807; called by muse, mutect2, varscan2
- OR2M3 | c.736T>A p.L246M | Missense Mutation (SNP) | VAF 82/232 reads (35%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as rs765106571, COSV101513473; called by muse, mutect2, varscan2
- OR2T3 | c.258G>T p.M86I | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.161); catalogued as COSV100613297; called by muse, mutect2, varscan2
- OR2T5 | c.227C>A p.A76E | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV100822203, COSV63540402; called by mutect2, varscan2
- OR52B2 | c.793C>G p.H265D | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as rs748845579, COSV101603954; called by muse, mutect2, varscan2
- OR5L1 | c.722G>C p.C241S | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100450120; called by muse, mutect2, varscan2
- P2RY12 | c.826C>G p.L276V | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV56399067, COSV99853815; called by muse, mutect2, varscan2
- PACS2 | c.655G>A p.G219R | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.092); catalogued as COSV100330640, COSV100330862; called by muse, mutect2, varscan2
- PASK | c.3451G>T p.A1151S | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99299830; called by muse, mutect2, varscan2
- PCDHA10 | c.10A>T p.R4* | Nonsense Mutation (SNP) | VAF 37/104 reads (36%) | catalogued as COSV100251940; called by muse, mutect2, varscan2
- PCDHGA4 | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.145); catalogued as COSV53932748; called by muse, mutect2, varscan2
- PHF20 | c.1027G>T p.D343Y | Missense Mutation (SNP) | VAF 48/89 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as COSV100180483, COSV59189720; called by muse, mutect2, varscan2
- PHLDB2 | c.848G>A p.R283Q | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as rs770741178, COSV67313677; called by muse, mutect2, varscan2
- PHYKPL | c.529C>T p.P177S | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.045); catalogued as COSV100069586; called by muse, mutect2, varscan2
- PITPNB | c.301G>T p.E101* | Nonsense Mutation (SNP) | VAF 8/33 reads (24%) | catalogued as COSV100086864; called by muse, mutect2, varscan2
- PLEKHA8 | c.1063G>T p.A355S | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99321915; called by muse, mutect2, varscan2
- PMFBP1 | c.2079A>T p.Q693H (on ENST00000537465; = p.Q688H on NM_031293.3) | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.799); catalogued as rs562267882, COSV99401196; called by muse, mutect2, varscan2
- PNPLA6 | c.3514G>A p.D1172N (on ENST00000414982 / NM_001166111.2; = p.D1124N on NM_006702.5) | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99654038; called by muse, mutect2, varscan2
- POU2F1 | c.1277G>T p.W426L (on ENST00000541643 / NM_001365848.1; = p.W449L on NM_002697.4) | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99611512; called by muse, mutect2, varscan2
- PPP1R13B | c.3043A>C p.K1015Q | Missense Mutation (SNP) | VAF 56/88 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV99160216; called by muse, mutect2, varscan2
- PRR12 | c.3271A>G p.T1091A (on ENST00000615927; = p.T1912A on NM_020719.3) | Missense Mutation (SNP) | VAF 31/50 reads (62%) | SIFT tolerated (0.25); PolyPhen benign (0.033); catalogued as COSV101330726; called by muse, mutect2, varscan2
- PTGER2 | c.365C>A p.A122D | Missense Mutation (SNP) | VAF 47/92 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99817569; called by muse, mutect2, varscan2
- PTPN12 | c.434G>C p.R145P | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99950490; called by muse, mutect2, varscan2
- PTPRZ1 | c.2192C>T p.S731F | Missense Mutation (SNP) | VAF 7/131 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.641); catalogued as COSV101100441; called by muse, mutect2
- PXDNL | c.1849G>T p.A617S | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761405633, COSV100684819; called by muse, mutect2, varscan2
- QRFPR | c.949G>A p.V317M | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs751553958, COSV57677217; called by muse, mutect2
- QRFPR | c.947T>C p.I316T | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.762); catalogued as COSV100543847; called by muse, mutect2
- RAB5C | c.362G>A p.R121K | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.956); catalogued as rs752617266, COSV100651450; called by muse, mutect2, varscan2
- RASGRF1 | c.1956T>A p.S652R | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV101174613; called by muse, mutect2, varscan2
- RIMS1 | c.4988C>T p.S1663L | Missense Mutation (SNP) | VAF 73/167 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53442613; called by muse, mutect2, varscan2
- RMND5B | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs370860902; called by muse, mutect2, varscan2
- ROBO4 | c.1402C>T p.P468S | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100127178, COSV100127700; called by muse, mutect2, varscan2
- RYR1 | c.5422C>T p.R1808W | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs759687640, COSV62102262; called by muse, mutect2
- SAP130 | c.1175C>T p.A392V | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.006); catalogued as rs372935713; called by muse, mutect2, varscan2
- SLC35B1 | c.667A>G p.T223A (on ENST00000649906; = p.T186A on NM_005827.4) | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99539550; called by mutect2, varscan2
- SLC45A1 | c.1076C>T p.T359M | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs372616601; called by muse, mutect2, varscan2
- SLC4A9 | c.1438C>T p.R480C (on ENST00000507527 / NM_001258428.2; = p.R456C on NM_031467.3) | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs774917090, COSV50187232; called by muse, mutect2, varscan2
- SLC5A8 | c.386T>C p.L129P | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV101610570; called by muse, mutect2, varscan2
- SLC8A3 | c.2231C>A p.A744D (on ENST00000381269 / NM_183002.3; = p.A742D on NM_033262.4) | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99385670; called by muse, mutect2, varscan2
- STXBP4 | c.1254G>T p.M418I | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV100894805; called by muse, mutect2, varscan2
- TAPT1 | c.1370A>G p.Y457C | Missense Mutation (SNP) | VAF 33/52 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs773452270, COSV100461188; called by muse, mutect2, varscan2
- TDP1 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs150113775; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TENM2 | c.4225G>A p.V1409I (on ENST00000518659 / NM_001122679.2; = p.V1170I on NM_001080428.3) | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101319064; called by muse, mutect2, varscan2
- TENM3 | c.3215A>G p.Y1072C | Missense Mutation (SNP) | VAF 120/165 reads (73%) | SIFT deleterious (0); PolyPhen benign (0.431); catalogued as rs745988097, COSV101305250; called by muse, mutect2, varscan2
- TENM3 | c.7763G>C p.G2588A | Missense Mutation (SNP) | VAF 12/12 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.147); catalogued as COSV101305251; called by muse, mutect2, varscan2
- THSD7A | c.487A>G p.K163E | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.576); catalogued as rs1554258047, COSV101448792; called by muse, mutect2, varscan2
- TIFAB | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as rs748636887, COSV101538261; called by muse, mutect2, varscan2
- TMEM131 | c.5545G>T p.A1849S | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.001); catalogued as COSV99488544; called by muse, mutect2, varscan2
- TMEM225 | c.85A>T p.T29S | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV100902837; called by muse, mutect2, varscan2
- TMOD1 | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.119); catalogued as COSV99403993; called by muse, varscan2
- TMTC2 | c.2391G>T p.K797N | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV100338391; called by muse, mutect2, varscan2
- TNN | c.2915-2A>G p.X972_splice | Splice Site (SNP) | VAF 21/68 reads (31%) | catalogued as rs770978560, COSV99512390; called by muse, mutect2, varscan2
- TTN | c.61163G>A p.R20388H (on ENST00000591111; = p.R12964H on NM_003319.4) | Missense Mutation (SNP) | VAF 7/55 reads (13%) | PolyPhen probably damaging (0.998); catalogued as rs72646868; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.24517del p.A8173Pfs*15 (on ENST00000591111; = p.A7246Pfs*15 on NM_133378.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 21/83 reads (25%) | catalogued as COSV60366400; called by mutect2, pindel, varscan2
- TUBG2 | c.1102C>T p.P368S | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.078); catalogued as rs751307110, COSV99257772; called by muse, mutect2
- USE1 | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.922); catalogued as rs1307399427, COSV99812540; called by muse, mutect2, varscan2
- XPOT | c.943A>G p.I315V | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV60349489; called by muse, mutect2, varscan2
- XPR1 | c.1924C>G p.L642V | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.348); catalogued as COSV100851492, COSV62558207; called by muse, mutect2, varscan2
- ZNF613 | c.1498A>T p.N500Y (on ENST00000293471 / NM_001031721.4; = p.N464Y on NM_024840.4) | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as COSV99523002; called by muse, mutect2, varscan2
- ZSCAN2 | c.890A>G p.Q297R | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs760990068, COSV100306926; called by muse, mutect2, varscan2
- FAM151B | c.701dup p.N234Kfs*2 | Frame Shift Ins (INS) | VAF 5/34 reads (15%) | called by mutect2, pindel
- GAGE1 | c.253G>A p.G85R | Missense Mutation (SNP) | VAF 39/175 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- HYDIN | c.2972C>T p.P991L | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- PCBP1 | c.811_823del p.W271Mfs*16 | Frame Shift Del (DEL) | VAF 16/104 reads (15%) | called by mutect2, pindel, varscan2
- USP34 | c.9937del p.I3313Ffs*8 | Frame Shift Del (DEL) | VAF 29/93 reads (31%) | called by mutect2, pindel, varscan2
- XXYLT1 | c.642_644del p.I214del | In Frame Del (DEL) | VAF 15/92 reads (16%) | called by mutect2, pindel, varscan2
- ATP4A | c.921G>T p.A307= | Silent (SNP) | VAF 84/159 reads (53%) | catalogued as rs371925816, COSV52866875, COSV99382821; called by muse, mutect2, varscan2
- BAZ2A | c.3651C>G p.P1217= | Silent (SNP) | VAF 3/10 reads (30%) | catalogued as COSV99466842; called by muse, mutect2
- C12orf40 | c.93A>G p.S31= | Silent (SNP) | VAF 14/27 reads (52%) | catalogued as COSV100210382; called by muse, mutect2, varscan2
- C2CD6 | c.849A>G p.P283= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as COSV99633699; called by muse, mutect2, varscan2
- FAM47C | c.2106C>A p.L702= | Silent (SNP) | VAF 36/60 reads (60%) | catalogued as COSV100792784; called by muse, mutect2, varscan2
- FARP1 | c.3033G>A p.A1011= | Silent (SNP) | VAF 33/58 reads (57%) | catalogued as rs376915595; called by muse, mutect2, varscan2
- FAT3 | c.11814G>A p.V3938= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as rs1186254337, COSV99967763; called by muse, mutect2, varscan2
- FIBCD1 | c.1368G>A p.P456= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as rs779048243, COSV99447313; called by muse, mutect2
- GRIK5 | c.1227G>A p.S409= | Silent (SNP) | VAF 15/135 reads (11%) | catalogued as rs201120893, COSV99490194; called by muse, mutect2, varscan2
- HECTD2 | c.735T>G p.S245= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV99978773; called by mutect2, varscan2
- HOXA9 | c.54C>T p.G18= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as rs753751095, COSV100604457; called by muse, mutect2, varscan2
- HSD17B2 | c.1017G>A p.T339= | Silent (SNP) | VAF 23/109 reads (21%) | catalogued as rs372570633; called by muse, mutect2, varscan2
- ITGAX | c.2319C>T p.A773= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as rs1016765276, COSV51642692; called by muse, mutect2, varscan2
- IZUMO1 | c.828G>A p.S276= | Silent (SNP) | VAF 30/50 reads (60%) | catalogued as COSV99710923; called by muse, mutect2, varscan2
- KAT2B | c.330C>T p.G110= | Silent (SNP) | VAF 37/82 reads (45%) | catalogued as COSV99769562; called by muse, mutect2, varscan2
- LHCGR | c.1719C>T p.I573= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as COSV99683910; called by muse, mutect2, varscan2
- LYST | c.4096C>T p.L1366= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV101089880; called by muse, mutect2
- MUC5B | c.9030C>A p.A3010= | Silent (SNP) | VAF 83/193 reads (43%) | catalogued as rs371259202; called by muse, mutect2, varscan2
- MYO1G | c.2164C>A p.R722= | Silent (SNP) | VAF 25/65 reads (38%) | catalogued as COSV51856102, COSV99348900; called by muse, mutect2, varscan2
- NAP1L1 | c.243C>G p.L81= | Silent (SNP) | VAF 26/73 reads (36%) | catalogued as COSV53873739, COSV99673937; called by muse, mutect2, varscan2
- NEK7 | c.549C>T p.G183= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV100954734; called by muse, mutect2
- NEXMIF | c.2475A>T p.S825= | Silent (SNP) | VAF 36/58 reads (62%) | catalogued as COSV99281204; called by muse, mutect2, varscan2
- NRAP | c.525A>T p.T175= | Silent (SNP) | VAF 34/94 reads (36%) | catalogued as COSV100748500; called by muse, mutect2, varscan2
- OR13G1 | c.450C>T p.V150= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as COSV100687365; called by muse, mutect2, varscan2
- OR4C12 | c.729A>T p.I243= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV100078597; called by muse, mutect2, varscan2
- OR5F1 | c.207G>A p.V69= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV99558744; called by muse, mutect2, varscan2
- OR5P3 | c.648A>T p.I216= | Silent (SNP) | VAF 25/47 reads (53%) | catalogued as rs374173943; called by muse, mutect2, varscan2
- OR5R1 | c.549C>A p.P183= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as COSV100393512, COSV100393558; called by muse, mutect2, varscan2
- PCDHA11 | c.2031C>G p.A677= | Silent (SNP) | VAF 17/73 reads (23%) | catalogued as COSV100251941, COSV56503414; called by muse, mutect2, varscan2
- PDF | c.423G>A p.A141= | Silent (SNP) | VAF 14/23 reads (61%) | catalogued as COSV99846554; called by muse, mutect2, varscan2
- PROKR2 | c.888C>T p.I296= | Silent (SNP) | VAF 21/90 reads (23%) | catalogued as COSV54087458; called by muse, mutect2, varscan2
- PUS10 | c.693A>C p.P231= | Silent (SNP) | VAF 33/75 reads (44%) | catalogued as COSV57451904; called by muse, mutect2, varscan2
- RANGAP1 | c.1623G>T p.A541= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as COSV100663788; called by muse, mutect2, varscan2
- SCN4A | c.5484C>G p.R1828= | Silent (SNP) | VAF 4/90 reads (4%) | catalogued as COSV101438561; called by muse, mutect2
- SDK1 | c.2460G>C p.R820= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV101269578, COSV67360768; called by muse, mutect2, varscan2
- SEMA4B | c.279C>T p.L93= | Silent (SNP) | VAF 16/69 reads (23%) | catalogued as COSV100203198; called by muse, mutect2, varscan2
- SERPIND1 | c.1437C>T p.I479= | Silent (SNP) | VAF 29/91 reads (32%) | catalogued as COSV99300297; called by muse, mutect2
- SHROOM1 | c.150G>A p.P50= | Silent (SNP) | VAF 3/9 reads (33%) | catalogued as rs1435128354, COSV100167175; called by muse, mutect2
- SORCS3 | c.2838C>A p.T946= | Silent (SNP) | VAF 29/155 reads (19%) | catalogued as rs1350299700, COSV100863663; called by muse, mutect2, varscan2
- TERF2 | c.1215C>T p.V405= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV99651593; called by muse, mutect2
- TOP3B | c.870G>A p.R290= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV100592615; called by muse, mutect2
- TTC21B | c.3495G>A p.T1165= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as rs147524050; ClinVar: likely benign; called by muse, mutect2, varscan2
- UGT2B7 | c.846C>T p.C282= | Silent (SNP) | VAF 61/146 reads (42%) | catalogued as COSV100535242; called by muse, mutect2, varscan2
- VEPH1 | c.1476G>C p.L492= | Silent (SNP) | VAF 23/120 reads (19%) | catalogued as COSV100747751; called by muse, mutect2, varscan2
- ZGPAT | c.1098G>T p.V366= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV100203212; called by muse, mutect2, varscan2
- ZMAT1 | c.1746G>A p.E582= | Silent (SNP) | VAF 32/49 reads (65%) | catalogued as COSV100858855; called by muse, mutect2, varscan2
- ZNF514 | c.1083A>G p.Q361= | Silent (SNP) | VAF 19/65 reads (29%) | catalogued as rs758492586, COSV99727830; called by muse, mutect2, varscan2
- AC024940.1 | n.2428T>C | RNA (SNP) | VAF 12/63 reads (19%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73846254 G>A | 5'Flank (SNP) | VAF 20/36 reads (56%) | catalogued as rs369585036; called by muse, mutect2, varscan2
- SLC22A17 | n.810G>T | RNA (SNP) | VAF 18/54 reads (33%) | catalogued as COSV52835424; called by muse, mutect2, varscan2
